Gene-level copy-number profile of tumor specimen TCGA-AN-A0AR-01A from TCGA case TCGA-AN-A0AR, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 55.2 years (20,152 days).
Specimen TCGA-AN-A0AR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.f6743da4-ebb2-4223-ba29-2b1a0859181f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0AR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc5ca5e4-2bfa-47b2-bd64-fb9ccd3095ee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 20,915; copy number 2: 28,471; copy number 3: 8,273; copy number 4: 1,272; copy number 5: 525; copy number 6: 228; copy number 7: 38; copy number 8: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0AR-01A-11D-A011-01): tumor purity 0.91, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,268,709–35,422,058, 6 genes: ZMYM4, RN7SL503P, SNORA62, RPL5P4, ZMYM4-AS1, Metazoa_SRP.
- chr9:97,853,226–99,154,192, 26 genes: FOXE1, TRMO, Y_RNA, AL499604.1, HEMGN, ANP32B, AL354726.1, RNU6-918P, NANS, TRIM14, Metazoa_SRP, CORO2A, TBC1D2, MIR6854, AL360081.1, GABBR2, SEPTIN7P7, ANKS6, AL807776.1, GALNT12, AL136084.1, NME2P3, COL15A1, AL136084.2, TGFBR1, RNA5SP290.
- chr15:94,273,496–94,274,005, 1 gene: AC135626.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 815 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:194,718,795–194,719,236, 1 gene, copy number 5: AL353072.1.
- chr2:182,716,041–183,215,414, 13 genes, copy number 6: DNAJC10, RPL31P15, Y_RNA, FRZB, RNU6-1122P, NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35, AC021851.1.
- chr2:183,260,642–183,261,046, 1 gene, copy number 6: LIN28AP1.
- chr5:1,639,627–3,601,403, 30 genes, copy number 5 (within-gene range 4–5): AC026412.4, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1.
- chr5:13,553,654–29,983,114, 201 genes, copy number 5–6 (broad region; genes not listed).
- chr6:1,312,098–2,917,733, 28 genes, copy number 5–6: FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1, AL359852.2, AL359852.1, LINC02521, LINC01600, MYLK4, WRNIP1, SERPINB1, SERPINB9P1, MIR4645, SERPINB9, AL133351.2, AL133351.1.
- chr6:21,233,168–22,654,455, 16 genes, copy number 5 (within-gene range 3–5): AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1.
- chr6:72,967,687–74,004,812, 34 genes, copy number 5: MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109, AL590552.1, TXNP7.
- chr6:106,969,831–107,133,170, 4 genes, copy number 5: CD24, MTRES1, BEND3, RNU6-1299P.
- chr6:107,192,300–107,230,152, 2 genes, copy number 5: AL591516.1, RPS24P12.
- chr6:137,900,585–138,344,663, 7 genes, copy number 8: AL591468.1, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1.
- chr9:12,287,320–14,532,042, 26 genes, copy number 5–8: JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1.
- chr10:8,045,378–8,724,288, 12 genes, copy number 5: GATA3, GATA3-AS1, AL390294.1, PRPF38AP1, LINC00708, AL390835.1, AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1.
- chr10:11,453,946–13,099,652, 27 genes, copy number 7 (within-gene range 4–7): USP6NL, AL512631.2, AL512631.1, ECHDC3, PROSER2, PROSER2-AS1, UPF2, RNU6-1095P, DHTKD1, RNU6-88P, SEC61A2, MIR548AK, NUDT5, CDC123, AL512770.1, RN7SL198P, CAMK1D, AL391314.1, RNU6ATAC39P, AL731559.1, MIR4480, MIR4481, MIR548Q, AL353586.1, CCDC3, RNA5SP300, RPL5P25.
- chr11:108,222,832–108,369,102, 1 gene, copy number 6 (within-gene range 3–6): ATM.
- chr11:108,308,519–108,593,768, 3 genes, copy number 6: C11orf65, POGLUT3, EXPH5.
- chr12:1,970,786–10,599,669, 351 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:33,355,206–33,676,796, 3 genes, copy number 5 (within-gene range 3–5): AL139383.1, AL161719.1, AL139081.1.
- chr15:101,281,510–101,614,531, 11 genes, copy number 7 (within-gene range 4–7): SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348.
- chr17:4,833,340–5,501,006, 44 genes, copy number 6 (within-gene range 3–6): MINK1, ATP6V0CP1, RN7SL784P, CHRNE, C17orf107, GP1BA, SLC25A11, RNF167, PFN1, ENO3, SPAG7, CAMTA2, AC004771.3, MIR6864, MIR6865, AC004771.1, AC004771.4, AC004771.2, INCA1, KIF1C, KIF1C-AS1, SLC52A1, AC012146.1, AC012146.2, ZFP3, ZNF232, ZNF232-AS1, USP6, AC012146.3, ZNF594, AC087500.1, SCIMP, AC087500.2, RABEP1, NUP88, AC015727.1, RPAIN, AC004148.1, C1QBP, DHX33, DHX33-DT, DERL2, MIS12, AC055839.2.

Autosomal genes at a single copy (total copy number 1): 18,908. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
